Gene-level copy-number profile of specimen HCM-BROD-0451-C15-85C from HCMI case HCM-BROD-0451-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.0 years (25,951 days).
Specimen HCM-BROD-0451-C15-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9706a8db-e8da-46a3-bcbb-9d00647613f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0451-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/cb9e4378-e718-4f1f-8b07-a8bf837f50f0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,307; copy number 2: 4,981; copy number 3: 31,186; copy number 4: 15,936; copy number 5: 2,153; copy number 6: 454; copy number 7: 1,050; copy number 8: 674; copy number 9: 9; copy number 10: 5; copy number 11: 41; copy number 12: 2; copy number 13: 25; copy number 14: 1; copy number 15: 9; copy number 16: 47; copy number 17: 1; copy number 18: 1; copy number 54: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,866 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,645,278, 6 genes, copy number 8: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr8:6,036,433–6,708,224, 10 genes, copy number 7–9: AC079054.1, AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055.
- chr8:11,982,321–12,194,133, 19 genes, copy number 7–15: DEFB135, DEFB134, AC107918.3, DEFB131E, AC107918.2, AC107918.1, DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1.
- chr8:12,205,759–12,206,389, 1 gene, copy number 9: ENPP7P12.
- chr8:12,310,962–12,665,588, 15 genes, copy number 7–18 (within-gene range 4–18): DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr8:60,289,928–98,294,393, 567 genes, copy number 7 (broad region; genes not listed).
- chr8:108,871,128–145,066,685, 534 genes, copy number 8 (broad region; genes not listed).
- chr9:61,642,383–61,662,690, 2 genes, copy number 7: Y_RNA, AL935212.1.
- chr12:24,212,421–26,335,856, 46 genes, copy number 11–16 (within-gene range 3–20): MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3.
- chr15:19,878,555–22,406,944, 129 genes, copy number 8 (broad region; genes not listed).
- chr15:88,459,477–101,979,093, 343 genes, copy number 7 (broad region; genes not listed).
- chr18:1,883,524–5,876,328, 71 genes, copy number 8–16 (within-gene range 5–16) (broad region; genes not listed).
- chr20:44,694,892–45,791,932, 56 genes, copy number 7 (within-gene range 6–7): KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1, WFDC5, WFDC12, PI3, SEMG1, SEMG2, AL035660.1, AL035660.2, SLPI, MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617, SPINT4, HNRNPA1P3, WFDC3, SPINT5P.
- chr20:47,826,969–48,074,188, 9 genes, copy number 7: RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1.
- chr20:48,624,252–48,849,458, 3 genes, copy number 7: PREX1, AL035106.1, AL133342.1.
- chr20:49,293,394–49,915,529, 10 genes, copy number 7 (within-gene range 6–7): KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2.
- chr20:50,888,916–51,131,667, 9 genes, copy number 7: ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1.
- chr20:58,389,229–59,516,039, 35 genes, copy number 7: VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1.
- chr21:8,603,547–8,603,984, 1 gene, copy number 54: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
